Somatic mutation profile of tumor specimen TCGA-WC-A87T-01A (aliquot TCGA-WC-A87T-01A-11D-A39W-08) from TCGA case TCGA-WC-A87T, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, type B; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 64.1 years (23,409 days).
Specimen TCGA-WC-A87T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0bf7138-e3da-43b7-a59e-c70a604c1e58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WC-A87T-10A (Blood Derived Normal), aliquot TCGA-WC-A87T-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b3604ca-1b05-44d9-bec0-1e68666ef666

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 36/74 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IQSEC3 | c.2329G>A p.D777N (on ENST00000538872 / NM_001170738.2; = p.D474N on NM_015232.1) | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555094828, COSV58288880; called by muse, mutect2, varscan2
- LMOD3 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs765223466; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSG1 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 117/200 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs200054291, COSV99741912; called by muse, mutect2, varscan2
- OSBPL2 | c.1364C>G p.P455R (on ENST00000313733 / NM_144498.4; = p.P443R on NM_014835.4) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF281 | c.1378A>G p.K460E | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (1); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
